Somatic mutation profile of tumor specimen TCGA-DG-A2KJ-01A (aliquot TCGA-DG-A2KJ-01A-11D-A18J-09) from TCGA case TCGA-DG-A2KJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 50.5 years (18,453 days).
Specimen TCGA-DG-A2KJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32d43207-40c5-4550-b8a2-b8cce9d42dc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DG-A2KJ-10A (Blood Derived Normal), aliquot TCGA-DG-A2KJ-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc53d567-17ee-4b1b-af39-374640ebba3f

The open-access MAF lists 93 somatic variants for this specimen: 65 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 26, Nonsense Mutation 3, Splice Site 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT8 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs762380579; called by muse, mutect2, varscan2
- ANAPC5 | c.1534C>A p.Q512K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs552135290; called by muse, mutect2, varscan2
- ARID2 | c.4373C>T p.S1458L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.604); catalogued as COSV57617443; called by muse, mutect2, varscan2
- ARRB2 | c.1151A>T p.D384V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV52619192; called by muse, mutect2, varscan2
- CAVIN2 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100414135; called by muse, mutect2, varscan2
- CD320 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs376511243; called by muse, mutect2, varscan2
- CHRDL2 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs764610716, COSV99734137; called by muse, mutect2, varscan2
- CSMD1 | c.3275G>A p.R1092H (on ENST00000520002; = p.R1091H on NM_033225.6) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs757014018, COSV59326703; called by muse, mutect2, varscan2
- ESYT2 | c.1432G>A p.E478K (on ENST00000613624; = p.E402K on NM_020728.3) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV99277139; called by muse, mutect2, varscan2
- GK2 | c.1502C>G p.A501G | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100725882; called by muse, mutect2, varscan2
- H3C8 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as COSV59952626; called by muse, mutect2, varscan2
- IGLV4-3 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766640848; called by muse, mutect2, varscan2
- ING1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV58168380; called by muse, mutect2, varscan2
- KMT2C | c.7197G>C p.K2399N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as COSV100069081, COSV51475792; called by muse, mutect2, varscan2
- LAMB2 | c.3367C>T p.R1123W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767072232, COSV59736771; called by muse, mutect2, varscan2
- MAG | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs756544453, COSV62699438; called by muse, mutect2, varscan2
- MYH13 | c.3821T>A p.I1274N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs778244040; called by muse, mutect2, varscan2
- PODNL1 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs746295709, COSV54307994; called by muse, mutect2, varscan2
- PYGL | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV53586692; called by muse, mutect2, varscan2
- RAD50 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1060501980, COSV54749464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RARA | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54195958, COSV99565369; called by muse, mutect2, varscan2
- RASD2 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53353603; called by muse, mutect2, varscan2
- RECQL | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as COSV59086070; called by muse, varscan2
- RILPL1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs199741406; called by muse, mutect2, varscan2
- SCO2 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as rs372731740; called by muse, mutect2, varscan2
- SCRIB | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267977106; called by muse, mutect2
- SEH1L | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV50818357; called by muse, mutect2, varscan2
- SEZ6L | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs769535333, COSV50660077, COSV50664790; called by muse, mutect2, varscan2
- SPIDR | c.1048G>A p.G350S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0.022); catalogued as COSV52385631; called by muse, mutect2, varscan2
- TRIM62 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV99357702; called by muse, mutect2
- TTC7B | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs763661174; called by muse, mutect2, varscan2
- UTP20 | c.4461G>T p.M1487I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV99881435; called by muse, mutect2, varscan2
- VAT1L | c.156del p.L53Sfs*28 | Frame Shift Del (DEL) | VAF 43/100 reads (43%) | catalogued as rs765360976; called by mutect2, pindel, varscan2
- XYLT1 | c.2851G>A p.A951T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs767349679; called by muse, mutect2, varscan2
- ZBTB24 | c.1371-1G>A p.X457_splice | Splice Site (SNP) | VAF 7/66 reads (11%) | catalogued as rs1474527522, COSV57781220; called by muse, mutect2
- APBB1IP | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ARHGEF7 | c.1683C>G p.N561K (on ENST00000375741 / NM_001113511.2; = p.N383K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- ARID3B | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ARL13B | c.693A>T p.K231N (on ENST00000394222 / NM_001174150.2; = p.K124N on NM_144996.4) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C2orf78 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAB39L | c.546T>A p.D182E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CAPZA3 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CD109 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- CHMP4C | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CILP | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- CRAMP1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CSNK2A1 | c.934_973+2del p.X312_splice | Splice Site (DEL) | VAF 35/62 reads (56%) | called by mutect2, pindel
- DAPK1 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH5 | c.11095C>T p.P3699S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- EIF2B1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FAM193A | c.2442G>T p.M814I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GGNBP2 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- GNAL | c.382G>A p.E128K (on ENST00000269162 / NM_001142339.3; = p.E205K on NM_182978.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- KIF22 | c.1547C>G p.S516* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- NELL2 | c.1574G>A p.C525Y | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- NICN1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- NSL1 | c.807G>C p.W269C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUGGC | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OR10G8 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SHOC2 | c.1638G>A p.M546I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- SLC36A3 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEKT5 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TJP1 | c.4178C>T p.S1393L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR36 | c.2637G>T p.M879I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ZNF808 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ADPRS | c.684C>T p.S228= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as rs764811203, COSV52881139; called by muse, mutect2, varscan2
- ARFGEF3 | c.3330G>A p.A1110= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV52450042; called by muse, mutect2
- ATG2A | c.2901C>T p.L967= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs1206111913; called by muse, mutect2, varscan2
- ATP8B1 | c.1254C>T p.F418= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV52174991; called by muse, mutect2, varscan2
- CAMK2G | c.738G>A p.K246= | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as COSV59483770; called by muse, mutect2, varscan2
- CCDC125 | c.624C>T p.N208= | Silent (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- CREBBP | c.4968C>G p.L1656= | Silent (SNP) | VAF 11/23 reads (48%) | called by muse, varscan2
- DPP4 | c.555C>A p.I185= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV62105456; called by muse, mutect2, varscan2
- IRAG2 | c.3279G>A p.S1093= (on ENST00000636465; = p.S138= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs368811607; called by muse, mutect2, varscan2
- KDELR3 | c.246C>T p.F82= | Silent (SNP) | VAF 48/148 reads (32%) | called by muse, mutect2, varscan2
- KIF20B | c.3372G>A p.L1124= (on ENST00000371728 / NM_001284259.2; = p.L1084= on NM_016195.4) | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV53316279; called by muse, mutect2, varscan2
- LRRC7 | c.1968G>A p.P656= (on ENST00000651989 / NM_001370785.2; = p.P623= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs780486664, COSV50409536; called by muse, mutect2, varscan2
- MEIOC | c.2145A>G p.L715= | Silent (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- MEP1A | c.2046C>T p.D682= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs762700833, COSV57922291; called by muse, mutect2, varscan2
- MTSS2 | c.990C>T p.F330= | Silent (SNP) | VAF 59/189 reads (31%) | catalogued as rs891663517, COSV58700038; called by muse, mutect2, varscan2
- NSUN4 | c.888C>G p.L296= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99047837; called by muse, mutect2, varscan2
- OR7C2 | c.147C>T p.I49= | Silent (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- PFKM | c.661C>T p.L221= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- PHF2 | c.2100G>A p.P700= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs768589231, COSV63683826; called by mutect2, varscan2
- PPP2R1A | c.1635G>A p.Q545= | Silent (SNP) | VAF 33/57 reads (58%) | catalogued as rs1423679899; called by muse, mutect2, varscan2
- PYROXD2 | c.999G>C p.V333= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV65331210; called by muse, mutect2, varscan2
- RERE | c.1833G>C p.R611= | Silent (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- RNF148 | c.249G>A p.Q83= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs995901413, COSV100411500; called by muse, mutect2, varscan2
- TRIM67 | c.90C>T p.C30= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.56916G>A p.Q18972= (on ENST00000591111; = p.Q11548= on NM_003319.4) | Silent (SNP) | VAF 47/173 reads (27%) | catalogued as rs1405518152; called by muse, mutect2, varscan2
- ZNF667 | c.1830C>G p.A610= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1323620268; called by muse, mutect2, varscan2
- CA10 | c.61+22841G>A | Intron (SNP) | VAF 20/73 reads (27%) | catalogued as rs1199045927; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7171G>T | Intron (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100875800; called by muse, mutect2, varscan2
